Gene-level copy-number profile of tumor specimen TCGA-QG-A5Z1-01A from TCGA case TCGA-QG-A5Z1, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 71.8 years (26,220 days).
Specimen TCGA-QG-A5Z1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.8fa9ad32-3405-41cf-acdf-9342444b374e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QG-A5Z1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0abf2082-877b-4f0d-ab67-51b317bdbd44

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 2: 8,312; copy number 3: 990; copy number 4: 42,167; copy number 5: 2,134; copy number 6: 1,372; copy number 7: 3,217; copy number 8: 623; copy number 9: 499; copy number 10: 127; copy number 11: 47; copy number 12: 10; copy number 13: 39; copy number 15: 255; copy number 17: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QG-A5Z1-01A-11D-A28F-01): tumor purity 0.8, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:66,504,959–67,521,844, 17 genes (within-gene range 0–4): ZWILCH, LCTL, LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 987 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–47,459,234, 575 genes, copy number 9–15 (broad region; genes not listed).
- chr13:73,036,401–74,555,515, 20 genes, copy number 12–17 (within-gene range 7–17): PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2.
- chr13:78,275,720–81,691,072, 39 genes, copy number 13 (within-gene range 7–13): AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr20:49,721,949–52,670,578, 63 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr20:52,972,358–64,313,132, 290 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
